TCGA case TCGA-12-0662 — Glioblastoma Multiforme (TCGA-GBM)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Gliomas; Primary site: Brain; Tissue source site: Duke. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/a3cc2845-8a44-4b50-8a3e-17a3c2c3e077

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 51 years; Vital status: Dead; Days to death: 1,161 days (3.2 years).

Diagnoses (2)
1. Glioblastoma (the primary disease): ICD-O-3 morphology code: 9440/3; ICD-10 code: C71.9; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Brain, NOS; Classification of tumor: primary; Age at diagnosis: 51.2 years (18,717 days); Year of diagnosis: 1998; Method of diagnosis: Excisional Biopsy; Prior treatment: No.
   Treatment given: Treatment type: Radiation, External Beam; Treatment intent type: Adjuvant; Days to treatment start: 47 days; Days to treatment end: 88 days; Treatment dose: 5,800 cGy; Number of fractions: 33; Treatment anatomic sites: Primary Tumor Field.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 120 days; Days to treatment end: 221 days; Number of cycles: 2; Treatment dose: 110 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 224 days; Days to treatment end: 278 days; Number of cycles: 2; Treatment dose: 100 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 278 days; Days to treatment end: 334 days; Treatment dose: 100 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Lomustine; Treatment intent type: Adjuvant; Days to treatment start: 340 days; Days to treatment end: 417 days (1.1 years); Number of cycles: 2; Treatment dose: 110 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Treatment intent type: Adjuvant; Days to treatment start: 417 days (1.1 years); Days to treatment end: 473 days (1.3 years); Number of cycles: 2; Treatment dose: 100 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Hormone Therapy; Therapeutic agents: Tamoxifen; Treatment intent type: Adjuvant; Days to treatment start: 473 days (1.3 years); Days to treatment end: 600 days (1.6 years); Treatment dose: 200 mg.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 600 days (1.6 years); Days to treatment end: 604 days (1.7 years); Number of cycles: 1; Treatment dose: 150 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 627 days (1.7 years); Days to treatment end: 844 days (2.3 years); Number of cycles: 7; Treatment dose: 200 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Carmustine Implant; Initial disease status: Progressive Disease; Days to treatment start: 876 days (2.4 years); Days to treatment end: 876 days (2.4 years); Number of cycles: 1; Treatment dose: 8 Wafer; Route of administration: Intratumoral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Irinotecan Hydrochloride; Initial disease status: Progressive Disease; Days to treatment start: 889 days (2.4 years); Days to treatment end: 1,028 days (2.8 years); Number of cycles: 3; Treatment dose: 75 mg/m2; Route of administration: Intravenous.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide; Initial disease status: Progressive Disease; Days to treatment start: 1,041 days (2.9 years); Days to treatment end: 1,070 days (2.9 years); Number of cycles: 1; Treatment dose: 100 mg; Route of administration: Oral.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Etoposide; Initial disease status: Progressive Disease; Days to treatment start: 1,041 days (2.9 years); Days to treatment end: 1,070 days (2.9 years); Number of cycles: 1; Treatment dose: 50 mg/m2; Route of administration: Oral.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Thalidomide; Initial disease status: Progressive Disease; Days to treatment start: 1,073 days (2.9 years); Days to treatment end: 1,090 days (3.0 years); Treatment dose: 400 mg.
   Treatment given: Treatment type: Immunotherapy (Including Vaccines); Therapeutic agents: Celecoxib; Initial disease status: Progressive Disease; Days to treatment start: 1,113 days (3.0 years); Days to treatment end: 1,161 days (3.2 years); Treatment dose: 400 mg; Route of administration: Oral.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: O6-Benzylguanine; Initial disease status: Progressive Disease; Days to treatment start: 1,133 days (3.1 years); Days to treatment end: 1,135 days (3.1 years); Treatment dose: 30 mg/m2.
   Treatment given: Treatment type: Targeted Molecular Therapy; Therapeutic agents: O6-Benzylguanine; Initial disease status: Progressive Disease; Days to treatment start: 1,133 days (3.1 years); Days to treatment end: 1,135 days (3.1 years); Treatment dose: 120 mg/m2.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Temozolomide; Initial disease status: Progressive Disease; Days to treatment start: 1,133 days (3.1 years); Days to treatment end: 1,137 days (3.1 years); Treatment dose: 10 mg/m2; Route of administration: Oral.
2. Progression of diagnosis 1 (Glioblastoma). Age at diagnosis: 52.9 years (19,317 days); Days to diagnosis: 600 days (1.6 years); Prior treatment: Yes.
   Treatment given: Treatment type: Surgery, NOS; Days to treatment start: 858 days (2.3 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Progressive Disease.
   Recorded as not given: Radiation Therapy, NOS; Radiation Therapy, NOS, for progressive disease.

Follow-up (4 entries)
- Day 600 (post initial treatment): Progression or recurrence: Yes; Days to progression: 600 days (1.6 years).
- Days to follow up: 1,161 days (3.2 years); Disease response: With Tumor.
- Karnofsky performance status: 80; Timepoint: Post Adjuvant Therapy.
- Progression or recurrence: Yes; Progression or recurrence type: Locoregional; Timepoint: Post Initial Treatment.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-12-0662-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Longest dimension: 0.9; Intermediate dimension: 0.8; Shortest dimension: 0.3.
  Slide TCGA-12-0662-01A-01-TS1: Section location: Top; Percent tumor cells: 95; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 5; Percent stromal cells: 0.
  Slide TCGA-12-0662-01A-01-BS1: Section location: Bottom; Percent tumor cells: 80; Percent tumor nuclei: 100; Percent normal cells: 0; Percent necrosis: 20; Percent stromal cells: 0.
- Sample TCGA-12-0662-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-12-0662-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Histologic diagnosis: Untreated primary (de novo) GBM; History lgg diagnosis of brain tissue: No; Tumor status: With tumor; History neoadjuvant treatment: No; Performance status timing: Post-Adjuvant Therapy.
- Drug treatment 1: Pharmaceutical therapy drug name: Gliadel Wafers.
- Drug treatment 1, Route of administrations: Route of administration: Intum.
- Drug treatment 2: Pharmaceutical therapy drug name: Cytoxan.
- Drug treatment 2, Route of administrations: Route of administration: PO.
- Drug treatment 4: Pharmaceutical therapy drug name: VP-16.
- Drug treatment 6: Pharmaceutical therapy drug name: Ccnu.
- Drug treatment 9: Pharmaceutical therapy drug name: Tamoxiten.
- Drug treatment 10: Pharmaceutical therapy drug name: Temodar.
- Drug treatment 11: Pharmaceutical therapy drug name: CPT-11.
- Drug treatment 11, Route of administrations: Route of administration: IV.
- Drug treatment 13: Pharmaceutical therapy drug name: 06GB.
- Drug treatment 16: Pharmaceutical therapy drug name: Celbrex.

GDC annotations on this case (curator notes; quoted as recorded):
- Item may not meet study protocol: Case identified (by Duke) as a secondary GBM; original annotation 06/22/09.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: event (deceased), 1,161 days; disease-specific survival: event (death attributed to the disease, the Clinical Data Resource's approximation), 1,161 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 600 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-12-0662-01A-01D-0333-01): tumor purity 0.69, ploidy 2.01, whole-genome doublings 0.
